MMRF case MMRF_1151 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b3a97996-7b5c-4f12-9a5e-c3f921081b06

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 250 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.8 years (26,238 days); ISS stage: III; Days to last known disease status: 250 days; Days to last follow up: 250 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 37 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 70 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 250 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 250.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 288 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.093 mg/dL; Immunoglobulin G 3.11 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 6.5 µg/mL; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 192 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 92 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 96.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 1.62 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.8 µg/mL; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 174 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 3.41 mmol/L.
- Day 182 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 107 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.089 mg/dL; Immunoglobulin G 1.11 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 5.73 µg/mL; Lactate Dehydrogenase 4.98 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 190 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.5 g/dL; Glucose 8.31 mmol/L.

Other clinical attributes
- Day 1: Weight: 92 kg; Height: 178 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1151_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1151_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
